TARGET case TARGET-30-PAMVRA — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b6c98e7c-1f25-5c9d-bece-d6fa15dd0248

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 2,433 days (6.7 years).

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 4.3 years (1,554 days); Year of diagnosis: 2004; Days to last follow up: 2,433 days (6.7 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Differentiating; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Necrosis percent: 10.
   Treatment given: Protocol identifier: A3973.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: AADM01P1.

Follow-up (1 entry)
- Days to follow up: 2,433 days (6.7 years); Days to first event: 2,433 days (6.7 years); First event: Death; Year of follow up: 2010.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (3 samples)
- Samples TARGET-30-PAMVRA-01A, TARGET-30-PAMVRA-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAMVRA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2433
- Protocol: ANBL00B1, A3973, AADM01P1
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.17
- Histology: Unfavorable
- MKI: Low
- Diagnostic Category: Ganglioneuroblastoma, nodular
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Percent Tumor: 75-85
